Somatic mutation profile of tumor specimen MMRF_1866_1_BM_CD138pos (aliquot MMRF_1866_1_BM_CD138pos_T1_KHS5U_L08689) from MMRF case MMRF_1866, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 58.5 years (21,354 days).
Specimen MMRF_1866_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f90d27a7-b80a-4530-8624-6b50802ca9cb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1866_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1866_1_PB_Whole_C2_KHS5U_L08688; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/785cb1ab-ed83-4e41-accb-3495891c9aac

The open-access MAF lists 100 somatic variants for this specimen: 42 protein-altering or splice-affecting, 10 silent, 48 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, 3'UTR 27, Intron 11, Silent 10, RNA 4, 5'UTR 3, Splice Site 2, 5'Flank 2, Nonsense Mutation 1, 3'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACOX1 | c.658+1G>T p.X220_splice | Splice Site (SNP) | VAF 72/127 reads (57%) | catalogued as rs779732414; called by muse, mutect2, varscan2
- ADGRL1 | c.4396G>A p.G1466R (on ENST00000340736 / NM_001008701.3; = p.G1461R on NM_014921.5) | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779694675, COSV61565137, COSV61565480; called by muse, mutect2, varscan2
- CPT1C | c.2291C>T p.A764V | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as rs1203357984; called by muse, mutect2, varscan2
- CSMD1 | c.8644G>A p.V2882M (on ENST00000520002; = p.V2881M on NM_033225.6) | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.6); catalogued as rs755414564, COSV59277894; called by mutect2, varscan2
- FAM131B | c.928C>T p.R310W | Missense Mutation (SNP) | VAF 120/264 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs534174916; called by muse, mutect2, varscan2
- GNB5 | c.218C>A p.A73D (on ENST00000261837 / NM_016194.4; = p.A31D on NM_006578.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.43); PolyPhen benign (0.006); catalogued as rs1270526972; called by muse, mutect2, varscan2
- H4C11 | c.175C>A p.L59M | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV100747965, COSV61827422; called by muse, mutect2, varscan2
- IFNAR2 | c.137G>A p.R46Q | Missense Mutation (SNP) | VAF 40/300 reads (13%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.661); catalogued as rs778792208, COSV59746370; called by muse, mutect2, varscan2
- IGHV1-69D | c.211A>G p.I71V | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs1310522022; called by muse, varscan2
- IGLL5 | c.116T>C p.L39P | Missense Mutation (SNP) | VAF 10/10 reads (100%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as rs532234272, COSV73249744; called by muse, mutect2, varscan2
- IGLV3-16 | c.172C>G p.P58A | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.048); catalogued as rs374894992; called by muse, mutect2, varscan2
- IGLV4-60 | c.227G>A p.S76N | Missense Mutation (SNP) | VAF 58/115 reads (50%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as rs369368652; called by muse, mutect2, varscan2
- MYH2 | c.2460C>G p.I820M | Missense Mutation (SNP) | VAF 52/112 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV55440710; called by muse, mutect2, varscan2
- PPP4R4 | c.535T>C p.S179P | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as rs1328485545; called by muse, mutect2, varscan2
- RGMA | c.1253G>A p.R418Q | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT tolerated (0.52); PolyPhen benign (0.013); catalogued as rs977379834; called by muse, mutect2
- STK25 | c.526G>A p.V176M | Missense Mutation (SNP) | VAF 49/93 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV50879555; called by muse, mutect2, varscan2
- TECRL | c.934A>C p.S312R | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1294824837; called by muse, mutect2, varscan2
- USH2A | c.5146G>T p.G1716* | Nonsense Mutation (SNP) | VAF 8/110 reads (7%) | catalogued as COSV100241064; called by muse, mutect2
- ZNF174 | c.173C>G p.S58C | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.533); catalogued as rs759151998; called by muse, mutect2, varscan2
- ACE2 | c.869A>G p.N290S | Missense Mutation (SNP) | VAF 66/67 reads (99%) | SIFT tolerated (0.41); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ATP2A1 | c.2488A>G p.S830G | Missense Mutation (SNP) | VAF 31/59 reads (53%) | SIFT tolerated (0.33); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BCAS1 | c.527A>C p.E176A | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- BCL11B | c.1109T>C p.L370P (on ENST00000357195 / NM_001282237.2; = p.L299P on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- BNC2 | c.2945C>T p.A982V | Missense Mutation (SNP) | VAF 11/230 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2
- C2orf73 | c.746C>A p.A249E | Missense Mutation (SNP) | VAF 85/172 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- DENND3 | c.1882C>G p.P628A | Missense Mutation (SNP) | VAF 40/82 reads (49%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FMR1 | c.1772A>T p.H591L | Missense Mutation (SNP) | VAF 53/55 reads (96%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- FRMD6 | c.629T>A p.L210Q (on ENST00000344768 / NM_001267046.2; = p.L202Q on NM_152330.4) | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- H3C8 | c.356C>G p.T119S | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- HEATR1 | c.957G>A p.K319= | Splice Region (SNP) | VAF 26/88 reads (30%) | called by muse, mutect2, varscan2
- IGHV1-69D | c.217A>C p.I73L | Missense Mutation (SNP) | VAF 37/115 reads (32%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, varscan2
- IGHV2-70D | c.54A>T p.L18F | Missense Mutation (SNP) | VAF 26/31 reads (84%) | SIFT deleterious (0.01); PolyPhen benign (0.017); called by muse, varscan2
- IGKV1D-43 | c.133T>C p.C45R | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- KANSL1 | c.2602A>T p.M868L (on ENST00000574590 / NM_001193465.2; = p.M869L on NM_015443.4) | Missense Mutation (SNP) | VAF 44/91 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- LAMA1 | c.5763A>C p.R1921S | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- POLQ | c.2522+2T>A p.X841_splice | Splice Site (SNP) | VAF 12/114 reads (11%) | called by muse, mutect2
- PPP1R9A | c.400C>G p.P134A | Missense Mutation (SNP) | VAF 61/135 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- PREX2 | c.1369C>G p.Q457E | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- SIPA1L2 | c.5082G>A p.M1694I | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by muse, mutect2
- TAS2R42 | c.518C>T p.T173I | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.33); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TFAP2A | c.814G>C p.D272H (on ENST00000482890; = p.D264H on NM_001032280.3) | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2
- TNFRSF11B | c.918A>C p.K306N | Missense Mutation (SNP) | VAF 79/156 reads (51%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BRCA1 | c.3762G>A p.K1254= | Silent (SNP) | VAF 98/206 reads (48%) | called by muse, mutect2, varscan2
- DCUN1D4 | c.142C>T p.L48= | Silent (SNP) | VAF 16/108 reads (15%) | called by muse, mutect2, varscan2
- DDX1 | c.444G>A p.G148= | Silent (SNP) | VAF 5/79 reads (6%) | called by muse, mutect2
- DNMT1 | c.747C>T p.T249= | Silent (SNP) | VAF 47/96 reads (49%) | called by muse, mutect2, varscan2
- IGHV2-70 | c.168C>T p.S56= | Silent (SNP) | VAF 18/45 reads (40%) | catalogued as rs367953381; called by muse, varscan2
- IGLV2-14 | c.99T>C p.P33= | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as rs752604605; called by muse, varscan2
- PDILT | c.510A>T p.I170= | Silent (SNP) | VAF 36/64 reads (56%) | called by muse, mutect2, varscan2
- PTGDS | c.474G>A p.E158= | Silent (SNP) | VAF 26/50 reads (52%) | catalogued as rs1439950953; called by muse, mutect2, varscan2
- SBSN | c.1314C>T p.D438= | Silent (SNP) | VAF 80/181 reads (44%) | catalogued as COSV71733350; called by muse, mutect2, varscan2
- TSPAN32 | c.414G>C p.T138= | Silent (SNP) | VAF 27/63 reads (43%) | called by muse, mutect2, varscan2
- ABHD4 | c.*968G>A | 3'UTR (SNP) | VAF 5/100 reads (5%) | called by muse, mutect2
- ADAMTS1 | c.*1112T>G | 3'UTR (SNP) | VAF 16/35 reads (46%) | catalogued as rs768112159; called by muse, mutect2, varscan2
- AKT2 | c.-84-9890G>A | Intron (SNP) | VAF 36/62 reads (58%) | catalogued as rs774180167; called by muse, mutect2, varscan2
- AP000769.5 | chr11:65499326 T>A | 5'Flank (SNP) | VAF 19/54 reads (35%) | catalogued as rs774838204; called by muse, mutect2, varscan2
- BTG1 | c.*941_*945del | 3'UTR (DEL) | VAF 31/63 reads (49%) | catalogued as rs1043257264; called by mutect2, pindel, varscan2
- C16orf72 | c.*3649T>C | 3'UTR (SNP) | VAF 15/44 reads (34%) | called by muse, mutect2, varscan2
- CACNG8 | c.*2412C>T | 3'UTR (SNP) | VAF 28/65 reads (43%) | called by muse, mutect2, varscan2
- CNTN1 | c.*218del | 3'UTR (DEL) | VAF 17/55 reads (31%) | called by mutect2, pindel, varscan2
- DPY19L2P2 | n.553T>C | RNA (SNP) | VAF 16/34 reads (47%) | catalogued as rs886385104; called by muse, mutect2, varscan2
- EDIL3 | c.-461del | 5'UTR (DEL) | VAF 42/87 reads (48%) | called by mutect2, pindel, varscan2
- EPC2 | c.313+2303T>A | Intron (SNP) | VAF 26/53 reads (49%) | called by muse, mutect2, varscan2
- FREM3 | c.*22dup | 3'UTR (INS) | VAF 22/62 reads (35%) | catalogued as rs530519833; called by mutect2, varscan2
- FUCA2 | c.1263+395T>G | Intron (SNP) | VAF 21/36 reads (58%) | called by muse, mutect2, varscan2
- GCLC | c.1091-116C>T | Intron (SNP) | VAF 15/42 reads (36%) | called by muse, mutect2, varscan2
- GUCY1B2 | n.1421A>C | RNA (SNP) | VAF 21/23 reads (91%) | called by muse, mutect2, varscan2
- HCAR3 | c.*416T>G | 3'UTR (SNP) | VAF 22/445 reads (5%) | called by muse, mutect2
- HOMER1 | c.*2171A>T | 3'UTR (SNP) | VAF 4/45 reads (9%) | called by muse, mutect2
- IGSF3 | c.*410C>T | 3'UTR (SNP) | VAF 23/52 reads (44%) | catalogued as COSV59591128; called by muse, mutect2, varscan2
- INHBE | c.*549C>T | 3'UTR (SNP) | VAF 11/22 reads (50%) | called by muse, mutect2, varscan2
- KPNA4 | c.*6996G>T | 3'UTR (SNP) | VAF 25/45 reads (56%) | called by muse, mutect2, varscan2
- KRTAP4-12 | c.*153C>A | 3'UTR (SNP) | VAF 11/32 reads (34%) | called by muse, mutect2, varscan2
- LACTB2 | c.286+1490C>T | Intron (SNP) | VAF 9/34 reads (26%) | catalogued as rs1448427797; called by muse, mutect2, varscan2
- LEKR1 | c.*505A>C | 3'UTR (SNP) | VAF 7/93 reads (8%) | catalogued as COSV62963231; called by muse, mutect2
- LRRC1 | c.-89A>C | 5'UTR (SNP) | VAF 37/75 reads (49%) | called by muse, mutect2, varscan2
- MIR4433B | n.79G>A | RNA (SNP) | VAF 9/17 reads (53%) | called by muse, mutect2, varscan2
- MIR5195 | chr14:106851256 T>C | 5'Flank (SNP) | VAF 46/105 reads (44%) | catalogued as rs749956333; called by muse, varscan2
- NAB1 | c.*2056T>A | 3'UTR (SNP) | VAF 15/33 reads (45%) | called by muse, mutect2, varscan2
- NDST3 | c.*1782C>G | 3'UTR (SNP) | VAF 4/15 reads (27%) | called by muse, mutect2, varscan2
- NKX6-3 | c.*1187A>G | 3'UTR (SNP) | VAF 5/25 reads (20%) | called by muse, varscan2
- NKX6-3 | c.*1104G>A | 3'UTR (SNP) | VAF 12/25 reads (48%) | called by muse, varscan2
- NOL4 | c.773-3848A>C | Intron (SNP) | VAF 20/37 reads (54%) | called by muse, mutect2, varscan2
- NPHP1 | c.1323+46A>T | Intron (SNP) | VAF 40/90 reads (44%) | called by muse, mutect2
- PEX2 | c.*1156G>C | 3'UTR (SNP) | VAF 16/48 reads (33%) | called by muse, mutect2
- PEX2 | c.*1155A>C | 3'UTR (SNP) | VAF 18/51 reads (35%) | called by muse, mutect2
- PHF21A | c.1785+106C>T | Intron (SNP) | VAF 35/78 reads (45%) | called by muse, mutect2
- PLXNC1 | c.3775+432C>T | Intron (SNP) | VAF 23/36 reads (64%) | called by muse, mutect2, varscan2
- PROX2 | c.*2044T>C | 3'UTR (SNP) | VAF 13/33 reads (39%) | called by muse, mutect2, varscan2
- SETD7 | c.*5292A>T | 3'UTR (SNP) | VAF 15/48 reads (31%) | called by muse, mutect2, varscan2
- SLC2A9 | c.151-126A>G | Intron (SNP) | VAF 11/18 reads (61%) | called by muse, mutect2, varscan2
- SMAD9 | c.*3335T>G | 3'UTR (SNP) | VAF 52/62 reads (84%) | called by muse, mutect2, varscan2
- SNF8 | c.422+33G>A | Intron (SNP) | VAF 13/113 reads (12%) | called by muse, mutect2, varscan2
- SNORD114-3 | n.41G>T | RNA (SNP) | VAF 10/113 reads (9%) | called by muse, mutect2
- SP9 | c.*395C>A | 3'UTR (SNP) | VAF 40/95 reads (42%) | called by muse, mutect2, varscan2
- STOX2 | c.-972G>A | 5'UTR (SNP) | VAF 13/85 reads (15%) | called by muse, mutect2, varscan2
- TMEM250 | c.*1604G>T | 3'UTR (SNP) | VAF 15/79 reads (19%) | called by muse, mutect2, varscan2
- TRIM67 | chr1:231221042 C>T | 3'Flank (SNP) | VAF 79/115 reads (69%) | catalogued as rs1207113030; called by muse, mutect2, varscan2
- TSPYL1 | c.*1743G>A | 3'UTR (SNP) | VAF 33/71 reads (46%) | called by muse, mutect2, varscan2
- WNK3 | c.*2671dup | 3'UTR (INS) | VAF 12/18 reads (67%) | catalogued as rs1472202745; called by mutect2, pindel, varscan2
